Somatic mutation profile of tumor specimen TCGA-BJ-A192-01A (aliquot TCGA-BJ-A192-01A-31D-A13W-08) from TCGA case TCGA-BJ-A192, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oxyphilic adenocarcinoma; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 54.4 years (19,878 days).
Specimen TCGA-BJ-A192-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15bf094d-5f1a-46d2-a23b-b8b383759823.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A192-10A (Blood Derived Normal), aliquot TCGA-BJ-A192-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed029b24-7731-48fc-b896-047b1cdb619d

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AOC1 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 43/159 reads (27%) | catalogued as COSV62866790; called by muse, mutect2, varscan2
- CDH12 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66387754; called by muse, mutect2
- KEAP1 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766297018, COSV50261116; called by muse, mutect2, varscan2
- LGALS13 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs752283904, COSV55679445; called by muse, mutect2, varscan2
- MSI1 | c.196G>T p.V66F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV99981621; called by mutect2, varscan2
- NFKBID | c.467C>T p.P156L (on ENST00000396901; = p.P308L on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1440823199, COSV61727733; called by muse, mutect2, varscan2
- MSI1 | c.194del p.F65Sfs*41 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | called by mutect2, varscan2
- ERAL1 | c.15C>T p.S5= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs746392707, COSV54739152; called by mutect2, varscan2
- GNAT1 | c.255C>T p.T85= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs779973193, COSV50028234; called by muse, mutect2, varscan2
- MIR876 | n.9T>G | RNA (SNP) | VAF 16/47 reads (34%) | catalogued as rs759906041; called by muse, mutect2, varscan2
